CCDI case PBBMIP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c973e6c2-69c0-42ef-95d2-ea73289a03b1

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.1 years (2,242 days).

Biospecimens (3 samples)
- Sample 0DDZ63: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DDZ6R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEK13: Tissue type: Tumor; Specimen type: Solid Tissue.
